Somatic mutation profile of tumor specimen TCGA-B4-5836-01A (aliquot TCGA-B4-5836-01A-11D-1669-08) from TCGA case TCGA-B4-5836, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 61.2 years (22,341 days).
Specimen TCGA-B4-5836-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f360446c-833e-4777-85f2-97c699f3e3c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B4-5836-10A (Blood Derived Normal), aliquot TCGA-B4-5836-10A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02083298-42b8-4028-80a9-a1c474515792

The open-access MAF lists 74 somatic variants for this specimen: 51 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 34, Silent 23, Frame Shift Del 7, Nonsense Mutation 5, In Frame Del 2, Frame Shift Ins 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.203C>A p.S68* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | hotspot (GDC flag); catalogued as rs869025617, CM003058, CM971566, COSV56542559, COSV56566398; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AFAP1L1 | c.662G>A p.C221Y | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99695737; called by muse, mutect2, varscan2
- AOC1 | c.1667A>G p.Q556R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV62868092; called by muse, mutect2, varscan2
- ASXL2 | c.1709C>G p.S570C | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as COSV55457266; called by muse, mutect2, varscan2
- ATP13A1 | c.2897C>T p.S966F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV52284728; called by muse, mutect2, varscan2
- CALCA | c.87G>A p.R29= | Splice Region (SNP) | VAF 5/43 reads (12%) | catalogued as COSV59027714; called by muse, mutect2, varscan2
- CCDC82 | c.805T>G p.C269G | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV53593022; called by muse, mutect2, varscan2
- DCAF13 | c.745A>G p.M249V | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as rs768651600, COSV52571418; called by muse, mutect2, varscan2
- DCAF17 | c.277A>C p.K93Q | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as COSV64544879; called by muse, mutect2, varscan2
- DFFB | c.702C>A p.S234R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.332); catalogued as COSV58860688; called by muse, mutect2, varscan2
- DNMT3A | c.2159G>C p.R720P | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV53039065, COSV53047637; called by muse, mutect2, varscan2
- FAM47C | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.559); catalogued as COSV63725671; called by muse, mutect2, varscan2
- GSTA5 | c.322C>G p.L108V | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV52861294; called by muse, mutect2, varscan2
- HPS4 | c.187T>A p.C63S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61103140; called by muse, mutect2, varscan2
- MCM5 | c.1508A>G p.N503S | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV53345872; called by muse, mutect2, varscan2
- METTL4 | c.1162A>T p.K388* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as COSV60603347; called by muse, mutect2, varscan2
- NCAPH | c.1218G>A p.M406I | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV53635946, COSV53637527; called by muse, mutect2, varscan2
- NOC3L | c.1889T>G p.L630R | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64929798; called by muse, mutect2, varscan2
- PAN3 | c.595A>T p.S199C | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV66708315; called by muse, mutect2
- PBRM1 | c.3394G>T p.E1132* (on ENST00000296302 / NM_001366071.2; = p.E1107* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 33/99 reads (33%) | catalogued as COSV56260755, COSV56265618; called by muse, mutect2, varscan2
- PHKA1 | c.3112C>G p.P1038A | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV59804661; called by muse, mutect2, varscan2
- PPFIA2 | c.3277A>G p.R1093G | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs935700362, COSV61028410; called by muse, mutect2
- PRPF8 | c.3385A>T p.N1129Y | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV59262467; called by muse, mutect2, varscan2
- PXK | c.776del p.G259Afs*7 | Frame Shift Del (DEL) | VAF 24/101 reads (24%) | catalogued as COSV57087410; called by mutect2, pindel, varscan2
- RAB11FIP5 | c.1662T>A p.S554R | Missense Mutation (SNP) | VAF 49/308 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV50248741; called by muse, mutect2, varscan2
- RXYLT1 | c.1202C>A p.T401N | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV54168126; called by muse, mutect2, varscan2
- SCN8A | c.1557G>C p.E519D | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.191); catalogued as COSV61979658; called by muse, mutect2, varscan2
- SH3BP2 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs772096716, COSV62553861; called by muse, mutect2, varscan2
- SIX5 | c.2117T>C p.L706P | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs891631182, COSV52177273; called by muse, mutect2, varscan2
- SLC16A2 | c.1088T>C p.I363T | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as COSV52083814; called by muse, mutect2
- TCERG1 | c.310A>G p.M104V | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1439899445, COSV57036274; called by muse, mutect2, varscan2
- TICRR | c.863T>A p.L288* | Nonsense Mutation (SNP) | VAF 30/111 reads (27%) | catalogued as COSV51540455; called by muse, mutect2, varscan2
- TRPC4 | c.1024G>T p.V342F | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV58997025; called by muse, mutect2, varscan2
- UBE2D2 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV54077732; called by muse, mutect2, varscan2
- WAPL | c.2111T>C p.F704S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53934169; called by muse, mutect2, varscan2
- WDR17 | c.985+2T>C p.X329_splice | Splice Site (SNP) | VAF 9/38 reads (24%) | catalogued as rs948801847, COSV54571842; called by muse, mutect2, varscan2
- WDR90 | c.527A>G p.N176S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.467); catalogued as COSV53468494; called by muse, mutect2, varscan2
- ZBTB8OS | c.129C>A p.Y43* | Nonsense Mutation (SNP) | VAF 17/100 reads (17%) | catalogued as COSV59385206; called by muse, mutect2, varscan2
- ZNF141 | c.1412A>G p.K471R | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53657979; called by muse, mutect2, varscan2
- ZNF397 | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV54350463; called by muse, mutect2, varscan2
- ZNF404 | c.1094G>A p.C365Y | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.022); catalogued as rs868010013, COSV60986941; called by mutect2, varscan2
- ZNF408 | c.1275A>T p.K425N | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV61237952; called by muse, mutect2, varscan2
- CNTLN | c.3668del p.K1223Rfs*8 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel, varscan2
- FAM83F | c.1343del p.K448Rfs*23 | Frame Shift Del (DEL) | VAF 15/93 reads (16%) | called by mutect2, pindel, varscan2
- GAPVD1 | c.2805del p.I935Mfs*130 (on ENST00000394104; = p.I962Mfs*172 on NM_015635.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | called by mutect2, pindel, varscan2
- MAPKAP1 | c.1119_1120del p.V374Tfs*5 (on ENST00000265960 / NM_001006617.3; = p.V338Tfs*5 on NM_024117.3) | Frame Shift Del (DEL) | VAF 10/99 reads (10%) | called by mutect2, pindel
- PLXDC2 | c.896_898del p.R299del | In Frame Del (DEL) | VAF 14/98 reads (14%) | called by pindel, varscan2
- SLC15A2 | c.1418dup p.L473Ffs*6 | Frame Shift Ins (INS) | VAF 56/276 reads (20%) | called by mutect2, pindel, varscan2
- TNIK | c.1721del p.S574Mfs*23 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- TRMT1L | c.825del p.K275Nfs*6 | Frame Shift Del (DEL) | VAF 22/149 reads (15%) | called by mutect2, pindel, varscan2
- VPS13D | c.3281_3283del p.M1094del | In Frame Del (DEL) | VAF 38/178 reads (21%) | called by mutect2, pindel, varscan2
- AFAP1L1 | c.663C>T p.C221= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV99695740; called by muse, mutect2, varscan2
- EMSY | c.492A>G p.A164= | Silent (SNP) | VAF 50/248 reads (20%) | catalogued as COSV58259255; called by muse, mutect2, varscan2
- EYA2 | c.60G>C p.L20= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV57941398, COSV57945410; called by muse, mutect2, varscan2
- FLG | c.9912C>A p.S3304= | Silent (SNP) | VAF 142/678 reads (21%) | catalogued as COSV64240225; called by muse, varscan2
- G6PC3 | c.195G>A p.E65= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV52242305; called by muse, mutect2, varscan2
- IRF2BP2 | c.1731A>T p.G577= | Silent (SNP) | VAF 60/207 reads (29%) | catalogued as COSV64014798; called by muse, mutect2, varscan2
- JMJD6 | c.1029C>T p.S343= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV58301170; called by muse, mutect2, varscan2
- KRT34 | c.1158C>T p.D386= | Silent (SNP) | VAF 26/160 reads (16%) | catalogued as rs141543111; called by muse, mutect2, varscan2
- MED22 | c.195C>G p.A65= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV59297846; called by muse, mutect2, varscan2
- MOB2 | c.237G>A p.T79= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs1351803509, COSV57318292; called by mutect2, varscan2
- MTOR | c.4389T>C p.Y1463= | Silent (SNP) | VAF 26/171 reads (15%) | catalogued as COSV63870116; called by muse, varscan2
- MYOCD | c.690C>T p.T230= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV58501630; called by muse, mutect2, varscan2
- NEUROD4 | c.807G>C p.G269= | Silent (SNP) | VAF 48/249 reads (19%) | catalogued as COSV54471206; called by muse, mutect2, varscan2
- OR2M2 | c.171C>A p.T57= | Silent (SNP) | VAF 77/385 reads (20%) | catalogued as rs1558246264, COSV62898141; called by muse, mutect2, varscan2
- PPARGC1A | c.984A>T p.S328= | Silent (SNP) | VAF 52/224 reads (23%) | catalogued as COSV53526700; called by muse, mutect2, varscan2
- SAGE1 | c.75A>C p.T25= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV61012630; called by muse, mutect2, varscan2
- SRPK1 | c.924A>G p.E308= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV60412216; called by mutect2, varscan2
- TBX5 | c.501A>C p.P167= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV59860117; called by muse, mutect2, varscan2
- TECPR1 | c.390T>C p.G130= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV65783115; called by muse, mutect2, varscan2
- TMEM91 | c.279C>T p.H93= | Silent (SNP) | VAF 165/788 reads (21%) | catalogued as rs200407337, COSV55370807; called by muse, mutect2, varscan2
- UROD | c.600C>T p.V200= | Silent (SNP) | VAF 25/126 reads (20%) | catalogued as COSV55799819; called by muse, mutect2, varscan2
- YOD1 | c.441T>C p.P147= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV60006141; called by muse, mutect2, varscan2
- ZNF511 | c.237G>A p.A79= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as rs1220991097, COSV62919773, COSV62919967; called by muse, mutect2, varscan2
